Somatic mutation profile of tumor specimen 0DVKE8 from CCDI case PBCMNS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 19.5 years (7,116 days).
Specimen 0DVKE8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b54dc2f5-5ba4-4383-9e12-25ebdd9f8f72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKEE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bee724d1-9359-48f9-9583-3a8958c93607

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AICDA | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 207/1002 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57563480; called by muse, varscan2
- C19orf38 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 138/234 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs962987520; called by muse, varscan2
- SELENBP1 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 330/816 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs765918794, COSV64373984, COSV64374208; called by muse, varscan2
- SGCZ | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 406/710 reads (57%) | catalogued as rs1404321308; called by muse, varscan2
- SLC4A2 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 462/548 reads (84%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs145331845; called by muse, varscan2
- TNXB | c.9430G>T p.V3144F (on ENST00000647633; = p.V2897F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/355 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs1056246867, COSV64483510; called by muse, varscan2
- ZMAT1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 270/309 reads (87%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201119309, COSV65658892; called by muse, varscan2
- YLPM1 | c.5818C>T p.H1940Y | Missense Mutation (SNP) | VAF 308/1127 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, varscan2
- FCHSD1 | c.777C>T p.A259= | Silent (SNP) | VAF 206/885 reads (23%) | catalogued as rs369917457; called by muse, varscan2
- MAP1B | c.1386G>A p.P462= | Silent (SNP) | VAF 240/1198 reads (20%) | catalogued as rs368021857; called by muse, varscan2
- TNXB | c.9429G>T p.G3143= (on ENST00000647633; = p.G2896= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 158/354 reads (45%) | catalogued as COSV100926796; called by muse, varscan2
- FTHL18 | n.1G>A | RNA (SNP) | VAF 181/213 reads (85%) | catalogued as rs1209670483; called by muse, varscan2
- GRM5 | c.*33C>T | 3'UTR (SNP) | VAF 243/673 reads (36%) | catalogued as COSV59636719; called by muse, varscan2
